CCDI case PBBSKG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/9e167234-0c0b-41d9-a5b6-6b86ee8cf3b7

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Myxoid liposarcoma: ICD-O-3 morphology code: 8852/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.2 years (5,570 days).

Biospecimens (3 samples)
- Sample 0DFMJ2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFMJ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFMJ6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
